MMRF case MMRF_1285 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c81e90b8-083c-4948-8c4c-9abb1e262dfe

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.3 years (27,512 days); ISS stage: I; Days to last known disease status: 1,570 days (4.3 years); Days to last follow up: 1,570 days (4.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 204 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 303 days; Days to treatment end: 877 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 898 days (2.5 years); Days to treatment end: 1,051 days (2.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,093 days (3.0 years); Days to treatment end: 1,205 days (3.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,280 days (3.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27 (ECOG 0): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 79.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.324 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.14 µg/mL; Hemoglobin 8.74 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.48 mmol/L; Albumin 49 g/L; Total Protein 7.5 g/dL; Glucose 5.89 mmol/L.
- Day 55 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Immunoglobulin G 7.3 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.1 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 8.31 mmol/L.
- Day 176 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 4.96 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 1.67 µg/mL; Hemoglobin 8.93 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 245 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.694 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Hemoglobin 8.74 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6 g/dL; Glucose 5.61 mmol/L.
- Day 322 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.859 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.33 mg/dL; Hemoglobin 9.67 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 6.4 g/dL; Glucose 4.51 mmol/L.
- Day 427 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.338 mg/dL; Hemoglobin 9.3 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 5.83 mmol/L.
- Day 511 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.858 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.36 mg/dL; Hemoglobin 9.55 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 6.33 mmol/L.
- Day 616 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Hemoglobin 9.3 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.4 g/dL; Glucose 6.11 mmol/L.
- Day 705 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 7.81 g/L; Hemoglobin 9.67 mmol/L; Leukocytes 6.2 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Total Protein 6.8 g/dL; Glucose 6.77 mmol/L.
- Day 789 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 11 g/L; Hemoglobin 9.8 mmol/L; Leukocytes 6.6 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.48 mmol/L; Albumin 47 g/L; Total Protein 7.1 g/dL; Glucose 7.59 mmol/L.
- Day 873 (ECOG 0): M Protein 0.74 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 12.6 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 5.8 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.43 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 6.93 mmol/L.
- Day 978 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 8.7 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.23 mmol/L.
- Day 1,062 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 7 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 8.86 mmol/L.
- Day 1,148 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 12.2 g/L; Immunoglobulin A 2.16 g/L; Immunoglobulin M 0.78 g/L; Hemoglobin 9.42 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 4.62 mmol/L.
- Day 1,241 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Hemoglobin 8.87 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 7.54 mmol/L.
- Day 1,374 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 6.77 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 0.27 µg/mL; Hemoglobin 8.62 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 11.9 mmol/L.
- Day 1,433: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.22 mg/dL; Hemoglobin 9.05 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 8.03 mmol/L.
- Day 1,497 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Hemoglobin 9.42 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.67 mmol/L.
- Day 1,570: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 5.91 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 7.7 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.4 mmol/L.

Other clinical attributes
- Day -27: Weight: 80 kg; Height: 167 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (3 samples)
- Sample MMRF_1285_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_1285_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
- Sample MMRF_1285_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 873 days (2.4 years).
